Somatic mutation profile of tumor specimen TCGA-DD-AACA-01A (aliquot TCGA-DD-AACA-01A-11D-A40R-10) from TCGA case TCGA-DD-AACA, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 65.6 years (23,973 days).
Specimen TCGA-DD-AACA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4b2e56b-e2e7-425e-bd50-ab472765b771.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AACA-10A (Blood Derived Normal), aliquot TCGA-DD-AACA-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a76ecf07-8234-402e-9037-f5000d2c30c4

The open-access MAF lists 120 somatic variants for this specimen: 96 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 22, Nonsense Mutation 5, Splice Region 2, Frame Shift Ins 2, Frame Shift Del 2, 5'UTR 1, Splice Site 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 52/142 reads (37%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 20/57 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCG8 | c.1523T>G p.I508S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.033); catalogued as COSV99699870; called by muse, mutect2, varscan2
- ADAM28 | c.1772A>C p.E591A | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.698); catalogued as COSV99738814; called by muse, mutect2, varscan2
- ADAM30 | c.328T>G p.C110G | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101023886; called by muse, mutect2, varscan2
- ADAMTS12 | c.1973G>T p.C658F | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100711078; called by muse, mutect2, varscan2
- ADCY2 | c.1107A>G p.I369M | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100603025; called by muse, mutect2, varscan2
- ANAPC2 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV100119104; called by muse, mutect2, varscan2
- APOA1 | c.485A>C p.Q162P | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs780347391, COSV99369293; called by muse, mutect2, varscan2
- ARFGEF3 | c.58A>G p.I20V | Missense Mutation (SNP) | VAF 76/195 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV99293738; called by muse, mutect2, varscan2
- C5orf22 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs745442454, COSV57599943; called by muse, mutect2, varscan2
- CAMK2A | c.1339G>A p.A447T (on ENST00000348628 / NM_171825.2; = p.A458T on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.003); catalogued as rs748774194, COSV100652046; called by muse, mutect2, varscan2
- CDCP1 | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 65/129 reads (50%) | catalogued as COSV99944083; called by muse, mutect2, varscan2
- CDH15 | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.918); catalogued as rs773943777, COSV57024818; called by muse, mutect2, varscan2
- CDH2 | c.181A>T p.S61C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); catalogued as COSV99297103; called by muse, mutect2, varscan2
- CDH7 | c.504G>A p.V168= | Splice Region (SNP) | VAF 30/65 reads (46%) | catalogued as COSV100542526; called by muse, mutect2, varscan2
- CDKN1B | c.275del p.P92Rfs*27 | Frame Shift Del (DEL) | VAF 166/457 reads (36%) | catalogued as COSV57430859; called by mutect2, pindel, varscan2
- CHPF2 | c.2267G>C p.R756P | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99223106; called by muse, mutect2, varscan2
- CIRBP | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV58011635; called by muse, mutect2, varscan2
- CLEC2D | c.86C>G p.S29C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as COSV51993407, COSV99325023; called by muse, mutect2
- COL11A1 | c.3352C>A p.P1118T | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.417); catalogued as COSV62192162; called by muse, mutect2, varscan2
- COL4A5 | c.4109T>C p.I1370T | Missense Mutation (SNP) | VAF 40/51 reads (78%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100087961; called by muse, mutect2, varscan2
- COL5A1 | c.3656G>A p.G1219D | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100880039; called by muse, mutect2, varscan2
- CUBN | c.2620G>A p.V874I | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0.024); catalogued as COSV100912805; called by muse, mutect2
- DEFB129 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as COSV55731043, COSV99857470; called by muse, mutect2, varscan2
- EFR3A | c.493C>T p.R165* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99603056; called by muse, varscan2
- EXOC5 | c.1474A>G p.I492V | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.23); catalogued as rs370435401, COSV100567105; called by muse, mutect2, varscan2
- FEZF2 | c.1090G>T p.E364* | Nonsense Mutation (SNP) | VAF 29/72 reads (40%) | catalogued as COSV51862718, COSV99334780; called by muse, mutect2, varscan2
- FFAR2 | c.241G>T p.V81F | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV99876085; called by muse, mutect2, varscan2
- FLG | c.4958C>T p.S1653L | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.841); catalogued as COSV100911635; called by muse, mutect2, varscan2
- FNDC1 | c.2116G>A p.A706T | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.017); catalogued as rs772608315, COSV51939704, COSV51944003; called by muse, mutect2, varscan2
- FRMD4B | c.223G>T p.V75F | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV101273475; called by muse, mutect2, varscan2
- FYB2 | c.1701A>G p.L567= | Splice Region (SNP) | VAF 18/45 reads (40%) | catalogued as COSV100599579; called by muse, mutect2, varscan2
- GABRA6 | c.241G>T p.V81F | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.248); catalogued as COSV50877496; called by muse, mutect2, varscan2
- GGT1 | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV99958972; called by muse, mutect2, varscan2
- GRID1 | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.355); catalogued as rs762175531, COSV60020849; called by muse, mutect2, varscan2
- GYS1 | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs933420343, COSV54402838; called by muse, mutect2, varscan2
- HAAO | c.152G>A p.G51D | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99685408; called by muse, mutect2
- IFT43 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 37/51 reads (73%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99466187; called by muse, mutect2, varscan2
- IGKV1D-17 | c.254G>T p.S85I | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); catalogued as rs747996565; called by muse, mutect2, varscan2
- INHBE | c.445A>G p.R149G | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV99875301; called by muse, mutect2, varscan2
- IZUMO1 | c.826T>C p.S276P | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99710836; called by muse, mutect2, varscan2
- KCND3 | c.249C>A p.F83L | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100138082, COSV56185047; called by muse, mutect2, varscan2
- KIAA1217 | c.827C>T p.T276I | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.3); catalogued as rs777644018, COSV100908022; called by muse, mutect2, varscan2
- KIF26B | c.5419C>T p.R1807C | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as rs1320589019, COSV100832586; called by muse, mutect2
- KRT20 | c.757A>T p.N253Y | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.614); catalogued as COSV99391431; called by muse, mutect2, varscan2
- LAMA2 | c.5699T>C p.L1900S | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101370518; called by muse, mutect2, varscan2
- MED12 | c.3686T>A p.V1229E | Missense Mutation (SNP) | VAF 32/38 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV61335442; called by muse, mutect2, varscan2
- MFF | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.5); catalogued as COSV100449339; called by muse, mutect2, varscan2
- MILR1 | c.1021C>A p.L341I | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as COSV101660236; called by muse, mutect2
- MPDU1 | c.731A>C p.K244T | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as COSV100002092; called by muse, mutect2, varscan2
- MTRF1L | c.377A>G p.E126G | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs774580344, COSV100922462; called by muse, mutect2, varscan2
- MYEOV | c.226T>C p.S76P | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV100456659; called by muse, mutect2, varscan2
- MYO18A | c.4936C>T p.R1646W | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs200860055; called by muse, mutect2, varscan2
- NAPA | c.653T>G p.M218R | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99645775; called by muse, mutect2, varscan2
- NDNF | c.179C>G p.T60R | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.351); catalogued as COSV101113187; called by muse, mutect2, varscan2
- NGLY1 | c.1021G>C p.V341L | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as COSV99770576; called by muse, mutect2, varscan2
- NLRP7 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0.028); catalogued as rs752841539, COSV100052791; called by muse, mutect2, varscan2
- NPLOC4 | c.1411T>G p.F471V | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100480951; called by muse, mutect2, varscan2
- NUP133 | c.1115T>A p.L372Q | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99772992; called by muse, mutect2, varscan2
- OBSCN | c.5714T>A p.L1905Q | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs781560949, COSV99479413; called by muse, mutect2, varscan2
- PDE6B | c.298C>A p.R100S | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV55325504, COSV99727675; called by muse, mutect2, varscan2
- PER1 | c.1976C>T p.T659I | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV100424602; called by muse, mutect2, varscan2
- PLCL2 | c.2351A>G p.Y784C (on ENST00000615277 / NM_001144382.2; = p.Y658C on NM_015184.5) | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as rs774032875, COSV101196764; called by muse, mutect2, varscan2
- PLEKHG6 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1565455686, COSV99164301; called by muse, mutect2, varscan2
- PLG | c.523T>A p.Y175N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV99804744; called by muse, mutect2, varscan2
- PSD3 | c.1830-1G>T p.X610_splice | Splice Site (SNP) | VAF 18/40 reads (45%) | catalogued as COSV99676150; called by muse, mutect2, varscan2
- RANGAP1 | c.619A>G p.I207V | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV100663774; called by muse, mutect2
- REPS1 | c.1817A>G p.D606G (on ENST00000450536 / NM_001286611.2; = p.D605G on NM_031922.4) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.272); catalogued as COSV57809194; called by muse, mutect2, varscan2
- RTF1 | c.1820C>T p.S607F | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV101047872; called by muse, mutect2, varscan2
- SEC63 | c.2069G>A p.G690E | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100938402; called by muse, mutect2, varscan2
- SLAMF1 | c.464A>C p.N155T | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV99349339; called by muse, mutect2, varscan2
- SLC32A1 | c.1486A>G p.I496V | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.487); catalogued as COSV99462317; called by muse, mutect2, varscan2
- SLC5A5 | c.1663C>T p.R555C | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs754164167, COSV55834552, COSV99715104; called by muse, mutect2, varscan2
- SMAD7 | c.758T>C p.L253P | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV100052924; called by mutect2, varscan2
- SPRR1B | c.59A>C p.Q20P | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs201420448, COSV100198367; called by muse, mutect2, varscan2
- SRC | c.1337C>A p.S446* | Nonsense Mutation (SNP) | VAF 32/60 reads (53%) | catalogued as COSV100658096; called by muse, mutect2, varscan2
- SRL | c.1292T>C p.I431T | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as rs765196291, COSV101281343; called by muse, mutect2, varscan2
- TENM1 | c.7730A>T p.K2577M | Missense Mutation (SNP) | VAF 53/58 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100950214; called by muse, mutect2, varscan2
- TGFBI | c.914A>G p.D305G | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.99); catalogued as rs890309873, COSV100526523; called by muse, mutect2, varscan2
- TLN2 | c.2080C>T p.Q694* | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | catalogued as COSV100168433, COSV100169166; called by muse, mutect2, varscan2
- TMBIM6 | c.605A>G p.D202G | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99920722; called by muse, mutect2, varscan2
- TRIOBP | c.2128T>G p.S710A | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.334); catalogued as COSV100730892, COSV60376256; called by muse, mutect2, varscan2
- TTLL3 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 140/275 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100047583; called by muse, mutect2, varscan2
- TYRO3 | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99777686; called by muse, mutect2, varscan2
- USP45 | c.2413G>A p.A805T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100569728; called by muse, mutect2, varscan2
- USP7 | c.2579C>T p.T860I | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.903); catalogued as COSV100784204; called by muse, mutect2, varscan2
- VCP | c.71A>C p.N24T | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV100734226; called by muse, mutect2, varscan2
- XKR6 | c.926T>C p.I309T | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100440766; called by muse, mutect2, varscan2
- ZFHX4 | c.7919G>T p.R2640L | Missense Mutation (SNP) | VAF 130/231 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as COSV99263453; called by muse, mutect2, varscan2
- ZNF512 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.202); catalogued as COSV100820816; called by muse, mutect2, varscan2
- FCGBP | c.8920T>A p.S2974T | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- IGKV1-17 | c.254G>T p.S85I | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- NOX5 | c.1241_1253del p.F414Sfs*62 | Frame Shift Del (DEL) | VAF 23/67 reads (34%) | called by mutect2, pindel, varscan2
- PHTF1 | c.1361dup p.M454Ifs*46 | Frame Shift Ins (INS) | VAF 41/120 reads (34%) | called by mutect2, pindel, varscan2
- REEP6 | c.149_172del p.F50_L57del | In Frame Del (DEL) | VAF 12/32 reads (38%) | called by mutect2, varscan2
- ADAMTS9 | c.4122G>A p.E1374= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs1450580267, COSV99899564; called by muse, mutect2, varscan2
- AMER3 | c.2421C>A p.G807= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as COSV100366618; called by muse, mutect2, varscan2
- ANOS1 | c.798G>A p.V266= | Silent (SNP) | VAF 20/25 reads (80%) | catalogued as COSV99390947; called by muse, mutect2, varscan2
- BMS1 | c.1668C>T p.C556= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV100996722; called by muse, mutect2, varscan2
- CBLN2 | c.600C>G p.L200= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as COSV99504443; called by muse, mutect2, varscan2
- COL22A1 | c.708C>A p.T236= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV100278774; called by muse, mutect2, varscan2
- DNAH9 | c.11358C>A p.T3786= | Silent (SNP) | VAF 9/13 reads (69%) | catalogued as COSV52346398, COSV99306150; called by muse, mutect2, varscan2
- EPHA8 | c.1716G>A p.K572= | Silent (SNP) | VAF 6/105 reads (6%) | catalogued as COSV51305281; called by muse, mutect2
- HEPH | c.684C>T p.L228= (on ENST00000343002; = p.L282= on NM_138737.5) | Silent (SNP) | VAF 55/59 reads (93%) | catalogued as COSV57959803; called by muse, mutect2, varscan2
- KCNA3 | c.1134G>A p.S378= | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as rs764449826, COSV63902769; called by muse, mutect2, varscan2
- MICALL1 | c.105G>T p.L35= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV99317315; called by muse, mutect2, varscan2
- NAT9 | c.594T>G p.P198= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV99380080; called by muse, mutect2, varscan2
- PCDHA1 | c.2232G>C p.A744= | Silent (SNP) | VAF 60/138 reads (43%) | catalogued as COSV100974376, COSV100974390; called by muse, mutect2
- PDIA2 | c.1329T>C p.I443= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs1198973166, COSV99249889; called by muse, mutect2, varscan2
- PDXDC1 | c.13C>T p.L5= | Silent (SNP) | VAF 46/92 reads (50%) | catalogued as rs1174672723, COSV100363213; called by muse, mutect2, varscan2
- REV3L | c.7941A>G p.K2647= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV100725262; called by muse, mutect2, varscan2
- RNF145 | c.1644G>T p.V548= (on ENST00000424310 / NM_001199383.2; = p.V576= on NM_144726.2) | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV99193568; called by muse, mutect2, varscan2
- SIGLEC6 | c.477C>T p.G159= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV100585441; called by muse, mutect2, varscan2
- SLCO5A1 | c.192G>T p.V64= | Silent (SNP) | VAF 56/89 reads (63%) | catalogued as COSV99480173; called by muse, mutect2, varscan2
- STXBP5 | c.2748G>A p.V916= (on ENST00000321680 / NM_001127715.2; = p.V880= on NM_139244.4) | Silent (SNP) | VAF 39/105 reads (37%) | catalogued as COSV99470419; called by muse, mutect2, varscan2
- TST | c.660T>C p.D220= | Silent (SNP) | VAF 41/83 reads (49%) | catalogued as COSV99968203; called by muse, mutect2, varscan2
- ZBTB41 | c.1410A>G p.K470= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs1159840025, COSV100963164; called by muse, mutect2, varscan2
- INPPL1 | c.*2A>G | 3'UTR (SNP) | VAF 44/99 reads (44%) | catalogued as COSV99996301; called by muse, mutect2, varscan2
- VPS50 | c.-2A>T | 5'UTR (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99298215; called by muse, mutect2, varscan2
